CCDI case PBCGAB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/71a90a30-6395-494e-8a9d-382a7feb341e

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 11.6 years (4,228 days).

Biospecimens (2 samples)
- Samples 0DVDT7, 0DVDU6 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
